Somatic mutation profile of tumor specimen MMRF_2613_1_BM_CD138pos (aliquot MMRF_2613_1_BM_CD138pos_T1_KHS5U_L13286) from MMRF case MMRF_2613, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.4 years (25,731 days).
Specimen MMRF_2613_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87054ab8-e122-4e22-b712-4519f7a3bdf5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2613_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2613_1_PB_WBC_C3_KHS5U_L13287; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed457697-a186-402a-bfdb-674dc9f6682e

The open-access MAF lists 107 somatic variants for this specimen: 41 protein-altering or splice-affecting, 19 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 30, Silent 19, Intron 11, Frame Shift Del 3, 5'UTR 2, 5'Flank 2, Nonsense Mutation 2, Splice Site 1, Splice Region 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CCKBR | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747382508, COSV58098347, COSV58103191; called by muse, mutect2, varscan2
- DZIP1L | c.101A>G p.D34G | Missense Mutation (SNP) | VAF 64/291 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104403687; called by muse, mutect2, varscan2
- ELAVL4 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.082); catalogued as rs1259386502, COSV100836508; called by muse, mutect2, varscan2
- FAM47A | c.1541C>T p.T514M | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs878906003; called by muse, varscan2
- FAM47A | c.1502C>T p.T501M | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.108); catalogued as COSV60493807, COSV60494503; called by muse, varscan2
- FRRS1L | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 44/259 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73746967; called by muse, mutect2, varscan2
- GRM1 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as rs150213757; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.145G>C p.D49H (on ENST00000354667 / NM_031243.3; = p.D37H on NM_002137.4) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61161915; called by muse, mutect2, varscan2
- LRGUK | c.2423G>A p.R808H | Missense Mutation (SNP) | VAF 32/464 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs138421011, COSV53634221; called by muse, mutect2
- OR51Q1 | c.154C>A p.R52S | Missense Mutation (SNP) | VAF 26/614 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV56177934; called by muse, mutect2
- RELN | c.10199G>T p.G3400V | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV59016832; called by muse, mutect2, varscan2
- TARM1 | c.167G>A p.R56Q (on ENST00000616041 / NM_001330650.1; = p.R48Q on NM_001135686.3) | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as rs369139973; called by muse, mutect2
- ZNF793 | c.272G>T p.R91I | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.737); catalogued as COSV71324928, COSV71325194; called by muse, mutect2
- AGTR1 | c.769C>A p.Q257K | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ASMTL | c.312G>T p.K104N | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- BUD13 | c.1193G>A p.R398K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C2orf72 | c.635-2A>G p.X212_splice | Splice Site (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- CAMTA2 | c.3166C>G p.Q1056E | Missense Mutation (SNP) | VAF 62/277 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH17 | c.888G>T p.Q296H | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- COL12A1 | c.8464C>T p.R2822* | Nonsense Mutation (SNP) | VAF 47/168 reads (28%) | called by muse, mutect2, varscan2
- COL25A1 | c.710G>A p.G237D | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRISP2 | c.86del p.L29Cfs*2 | Frame Shift Del (DEL) | VAF 38/198 reads (19%) | called by mutect2, pindel, varscan2
- CSNK2A3 | c.248dup p.I84Dfs*31 | Frame Shift Ins (INS) | VAF 27/128 reads (21%) | called by mutect2, pindel, varscan2
- DCAF8 | c.1085G>C p.R362T | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HSPA8 | c.1251T>A p.N417K | Missense Mutation (SNP) | VAF 64/101 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGF2R | c.1656T>G p.I552M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.038); called by mutect2, varscan2
- IGHE | c.508del p.E170Sfs*48 | Frame Shift Del (DEL) | VAF 29/84 reads (35%) | called by mutect2, pindel, varscan2
- IGLL5 | c.290dup p.Y97* | Nonsense Mutation (INS) | VAF 47/133 reads (35%) | called by mutect2, pindel, varscan2
- KANSL1L | c.481A>G p.T161A | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KCND2 | c.1463C>A p.T488N | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LYST | c.2713G>A p.A905T | Missense Mutation (SNP) | VAF 18/223 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2
- NXPE4 | c.113A>C p.N38T | Missense Mutation (SNP) | VAF 308/538 reads (57%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2AJ1 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 123/287 reads (43%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- PML | c.2273_2275del p.E758del | In Frame Del (DEL) | VAF 58/117 reads (50%) | called by mutect2, varscan2
- SLC18B1 | c.42A>C p.G14= | Splice Region (SNP) | VAF 27/115 reads (23%) | called by muse, mutect2, varscan2
- TCHHL1 | c.2235G>T p.E745D | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- TEX13C | c.2562C>A p.N854K | Missense Mutation (SNP) | VAF 13/342 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.058); called by muse, mutect2
- TRIP12 | c.1669A>T p.I557F | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- TXNDC5 | c.1205del p.F402Sfs*24 | Frame Shift Del (DEL) | VAF 41/172 reads (24%) | called by mutect2, pindel, varscan2
- USH2A | c.15137T>C p.L5046S | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- COL6A5 | c.5319C>T p.S1773= (on ENST00000312481; = p.S1769= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/212 reads (17%) | called by muse, mutect2, varscan2
- CXADR | c.483A>G p.K161= | Silent (SNP) | VAF 38/83 reads (46%) | called by muse, mutect2, varscan2
- DNAH17 | c.2121C>T p.N707= | Silent (SNP) | VAF 54/312 reads (17%) | catalogued as rs201170230; called by muse, mutect2, varscan2
- EEF1A2 | c.894T>C p.A298= | Silent (SNP) | VAF 39/112 reads (35%) | called by muse, mutect2, varscan2
- FOXB2 | c.162A>T p.T54= | Silent (SNP) | VAF 34/326 reads (10%) | called by muse, mutect2, varscan2
- FSTL4 | c.1561C>T p.L521= | Silent (SNP) | VAF 43/148 reads (29%) | catalogued as COSV99531271; called by muse, mutect2, varscan2
- GPR179 | c.162G>A p.E54= | Silent (SNP) | VAF 11/232 reads (5%) | catalogued as rs1449061154; called by muse, mutect2
- HEPH | c.2857C>T p.L953= (on ENST00000343002; = p.L686= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/177 reads (34%) | catalogued as COSV57975170; called by muse, mutect2, varscan2
- HSPA8 | c.1146A>G p.G382= | Silent (SNP) | VAF 179/325 reads (55%) | called by muse, mutect2, varscan2
- HSPB2 | c.336C>T p.F112= | Silent (SNP) | VAF 84/263 reads (32%) | catalogued as rs782751614, COSV99909872; called by muse, mutect2, varscan2
- IGHJ4 | c.3C>T p.Y1= | Silent (SNP) | VAF 25/38 reads (66%) | catalogued as rs368028316; called by muse, varscan2
- INPP5E | c.63G>A p.R21= | Silent (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- LRSAM1 | c.1371C>T p.F457= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as rs571925919, COSV55938859; called by muse, mutect2, varscan2
- SLC37A2 | c.1398C>T p.L466= | Silent (SNP) | VAF 62/243 reads (26%) | catalogued as rs370792494; called by muse, mutect2, varscan2
- TACC2 | c.7140C>A p.P2380= (on ENST00000334433; = p.P458= on NM_006997.4) | Silent (SNP) | VAF 18/232 reads (8%) | called by muse, mutect2
- TBL1X | c.486G>A p.A162= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as rs374413930; called by mutect2, varscan2
- TECPR1 | c.723C>T p.T241= | Silent (SNP) | VAF 46/150 reads (31%) | called by muse, mutect2, varscan2
- ZFHX3 | c.2337G>A p.A779= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as rs991582949; called by muse, mutect2, varscan2
- ZFHX4 | c.5958G>A p.R1986= | Silent (SNP) | VAF 24/219 reads (11%) | called by muse, mutect2, varscan2
- AP1G2 | c.978-23A>T | Intron (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- ARAP3 | c.-17-198C>G | Intron (SNP) | VAF 22/133 reads (17%) | called by muse, mutect2, varscan2
- ARIH2 | chr3:48918586 C>G | 5'Flank (SNP) | VAF 94/202 reads (47%) | catalogued as COSV62706232; called by muse, mutect2, varscan2
- BCLAF1 | c.*57T>A | 3'UTR (SNP) | VAF 9/197 reads (5%) | called by muse, mutect2
- CACNG7 | chr19:53943190 C>T | 3'Flank (SNP) | VAF 16/242 reads (7%) | catalogued as rs1220268623; called by muse, mutect2
- CARD10 | c.1948-30C>A | Intron (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- CD55 | c.1060+122C>G | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- CHORDC1 | c.115-1322C>G | Intron (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- COL18A1 | c.3597+476T>C | Intron (SNP) | VAF 15/50 reads (30%) | catalogued as rs1049839481; called by muse, mutect2, varscan2
- DOCK3 | c.*822_*826delinsCTCT | 3'UTR (DEL) | VAF 26/131 reads (20%) | called by pindel, varscan2*
- DTWD2 | c.*3224C>G | 3'UTR (SNP) | VAF 4/95 reads (4%) | called by muse, mutect2
- FAM124A | c.*555C>T | 3'UTR (SNP) | VAF 14/61 reads (23%) | called by muse, mutect2, varscan2
- FASTKD2 | c.*665A>C | 3'UTR (SNP) | VAF 34/70 reads (49%) | called by muse, mutect2, varscan2
- FOXN2 | c.*1471G>A | 3'UTR (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- GAP43 | c.*547C>T | 3'UTR (SNP) | VAF 9/45 reads (20%) | catalogued as rs866198722; called by muse, mutect2, varscan2
- GMCL1 | c.*528C>T | 3'UTR (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- H2AC6 | c.*29G>A | 3'UTR (SNP) | VAF 145/457 reads (32%) | catalogued as COSV58417362; called by muse, mutect2, varscan2
- HID1 | c.1150-24C>G | Intron (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- HNF1B | c.*231G>A | 3'UTR (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- HPGDS | c.*134C>A | 3'UTR (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- HSPA8 | c.1323+100T>C | Intron (SNP) | VAF 249/448 reads (56%) | called by muse, mutect2, varscan2
- IGFBP5 | c.*3664C>T | 3'UTR (SNP) | VAF 13/107 reads (12%) | catalogued as rs1028101812, COSV52083088; called by muse, mutect2, varscan2
- KCND2 | c.-814C>G | 5'UTR (SNP) | VAF 58/259 reads (22%) | called by muse, mutect2, varscan2
- LIFR | c.*6214G>C | 3'UTR (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2, varscan2
- MAB21L3 | c.*1205G>A | 3'UTR (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- MAGEB3 | c.*396A>C | 3'UTR (SNP) | VAF 41/89 reads (46%) | catalogued as COSV100854617; called by muse, mutect2, varscan2
- MAP1A | c.*542T>C | 3'UTR (SNP) | VAF 54/200 reads (27%) | called by muse, mutect2, varscan2
- MOB4 | c.*630C>T | 3'UTR (SNP) | VAF 18/500 reads (4%) | catalogued as rs1388211145; called by muse, mutect2
- NEUROG2 | c.*492G>A | 3'UTR (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- PCNX1 | c.*3952G>A | 3'UTR (SNP) | VAF 22/48 reads (46%) | catalogued as rs543173956; called by muse, mutect2, varscan2
- PDE3A | c.*1813A>C | 3'UTR (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- PFKFB2 | c.*1345C>A | 3'UTR (SNP) | VAF 6/89 reads (7%) | called by muse, mutect2
- PPARGC1A | c.234+1715C>T | Intron (SNP) | VAF 4/42 reads (10%) | catalogued as rs1220750844; called by muse, mutect2, varscan2
- PRKCE | c.-224C>G | 5'UTR (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- PTPRH | c.2257+2318T>G | Intron (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- RBM33 | c.*3194G>A | 3'UTR (SNP) | VAF 21/140 reads (15%) | called by muse, mutect2, varscan2
- RPS9 | c.407+305T>G | Intron (SNP) | VAF 33/131 reads (25%) | called by muse, mutect2, varscan2
- SFRP5 | c.*157G>T | 3'UTR (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- SH2B2 | chr7:102283860 G>A | 5'Flank (SNP) | VAF 34/107 reads (32%) | called by muse, mutect2, varscan2
- SLC9A9 | c.*135G>T | 3'UTR (SNP) | VAF 63/107 reads (59%) | called by muse, mutect2, varscan2
- SPA17 | c.*1222G>A | 3'UTR (SNP) | VAF 45/130 reads (35%) | called by muse, mutect2, varscan2
- SPA17 | c.*2180T>C | 3'UTR (SNP) | VAF 9/144 reads (6%) | called by muse, mutect2
- TAL1 | c.*558G>A | 3'UTR (SNP) | VAF 32/74 reads (43%) | called by muse, varscan2
- TNIK | c.*1707C>A | 3'UTR (SNP) | VAF 22/128 reads (17%) | catalogued as rs1353610151; called by muse, varscan2
- TRAF5 | c.*2093G>A | 3'UTR (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- UBOX5 | c.*1525C>A | 3'UTR (SNP) | VAF 49/197 reads (25%) | called by muse, mutect2, varscan2
- WASF4P | n.1221T>G | RNA (SNP) | VAF 26/84 reads (31%) | catalogued as rs1223742453; called by muse, mutect2, varscan2
